Somatic mutation profile of tumor specimen 0DY8KP from CCDI case PBCRYI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Malignant peripheral nerve sheath tumor with rhabdomyoblastic differentiation; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 17.3 years (6,320 days).
Specimen 0DY8KP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 663f74f2-5ecc-4e83-b9cd-eb3f7dae2fe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY8KF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cdbf967-0ab6-45b1-93cc-6bafab49998a

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, 3'UTR 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC4 | c.1822G>T p.A608S | Missense Mutation (SNP) | VAF 199/608 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59466905; called by muse, varscan2
- C3 | c.3124C>T p.R1042W | Missense Mutation (SNP) | VAF 141/458 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550043629, CM108969, CM153559; called by muse, varscan2
- CDH2 | c.1879G>C p.D627H | Missense Mutation (SNP) | VAF 191/608 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52296999; called by muse, varscan2
- HGF | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 231/1064 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55945952; called by muse, varscan2
- OR13J1 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 135/250 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as rs775159054, COSV65069377; called by muse, varscan2
- TAS2R41 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 143/1076 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs779872662, COSV68764906; called by muse, varscan2
- TFR2 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 208/549 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1028494790; called by muse, varscan2
- WDFY3 | c.669G>C p.W223C | Missense Mutation (SNP) | VAF 272/768 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs773128588; called by muse, varscan2
- YARS1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 262/720 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778307213, COSV65113963; called by muse, varscan2
- ZNF497 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 230/428 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1197824835; called by muse, varscan2
- ATP6V1B1 | c.1488G>C p.E496D | Missense Mutation (SNP) | VAF 126/277 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, varscan2
- CDH2 | c.2001G>C p.K667N | Missense Mutation (SNP) | VAF 152/578 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.308); called by muse, varscan2
- DNAH17 | c.10613A>G p.Y3538C | Missense Mutation (SNP) | VAF 212/450 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- GSTA6P | n.53-1G>A | Splice Site (SNP) | VAF 226/686 reads (33%) | called by muse, varscan2
- NKD1 | c.1204C>G p.H402D | Missense Mutation (SNP) | VAF 178/568 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, varscan2
- NKD1 | c.1381C>A p.H461N | Missense Mutation (SNP) | VAF 145/400 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- OSBP2 | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 264/406 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, varscan2
- DNAJB4 | c.9A>G p.K3= | Silent (SNP) | VAF 110/500 reads (22%) | catalogued as rs1379073933; called by muse, varscan2
- HECTD4 | c.10929T>C p.D3643= | Silent (SNP) | VAF 166/576 reads (29%) | called by muse, varscan2
- NMUR1 | c.780G>A p.R260= | Silent (SNP) | VAF 97/296 reads (33%) | called by muse, varscan2
- RYR1 | c.7758G>A p.V2586= | Silent (SNP) | VAF 92/628 reads (15%) | called by muse, varscan2
- SP110 | c.657C>T p.S219= | Silent (SNP) | VAF 221/654 reads (34%) | called by muse, varscan2
- KIF5A | c.2023+56C>G | Intron (SNP) | VAF 49/146 reads (34%) | called by muse, varscan2
- OR2AP1 | c.*51G>C | 3'UTR (SNP) | VAF 64/209 reads (31%) | called by muse, varscan2
- RDM1 | c.*73C>T | 3'UTR (SNP) | VAF 54/115 reads (47%) | called by muse, varscan2
